Gene-level copy-number profile of tumor specimen TCGA-33-AAS8-01A from TCGA case TCGA-33-AAS8, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.3 years (21,675 days).
Specimen TCGA-33-AAS8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.06335044-a113-46ed-a262-c0b34e572c07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-AAS8-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9fd0f315-1c6b-48b9-9a4a-7cdc5fe577e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 21,051; copy number 2: 36,830; copy number 3: 537; copy number 4: 270; copy number 5: 445; copy number 6: 192; copy number 7: 7; copy number 8: 246; copy number 9: 45; copy number 10: 50; copy number 12: 17; copy number 14: 2; copy number 15: 39; copy number 16: 17; copy number 27: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-33-AAS8-01A-11D-A400-01): tumor purity 0.64, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,692,734–21,176,888, 10 genes (within-gene range 0–1): AL663074.2, SH2D5, AL663074.1, HP1BP3, EIF4G3, RNU7-200P, MIR1256, RPS15AP6, AL627311.1, HSPE1P27.
- chr3:11,272,309–11,557,665, 1 gene (within-gene range 0–1): ATG7.
- chr3:11,488,300–11,771,350, 5 genes (within-gene range 0–1): AC026185.1, AC022001.1, VGLL4, AC022001.2, AC022001.3.
- chr9:25,579,657–28,670,286, 35 genes: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,032 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:148,695,994–163,479,500, 258 genes, copy number 5 (broad region; genes not listed).
- chr3:164,670,878–198,222,513, 635 genes, copy number 5–15 (broad region; genes not listed).
- chr9:38,360,427–43,045,120, 139 genes, copy number 6–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,619. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
